Somatic mutation profile of tumor specimen TCGA-2G-AAGP-01A (aliquot TCGA-2G-AAGP-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGP, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 33.4 years (12,202 days).
Specimen TCGA-2G-AAGP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cd53669-e972-4988-9c13-9254922bfebc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGP-10A (Blood Derived Normal), aliquot TCGA-2G-AAGP-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/131df6bd-cce6-4374-835c-8f4d41d272ee

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREB5 | c.290G>A p.R97Q (on ENST00000357727 / NM_182898.4; = p.R90Q on NM_004904.3) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142741982, COSV63219001; called by muse, mutect2, varscan2
- JPT2 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50189037; called by muse, mutect2, varscan2
- ZNF555 | c.1109G>A p.C370Y | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62073936; called by muse, mutect2, varscan2
- ADAMTS20 | c.4816T>C p.F1606L | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRL1 | c.901C>T p.R301C (on ENST00000340736 / NM_001008701.3; = p.R296C on NM_014921.5) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID4A | c.3436C>G p.P1146A | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHERP | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- HIVEP2 | c.4741A>G p.S1581G | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- KATNAL2 | c.338T>C p.M113T (on ENST00000356157 / NM_001353899.1; = p.M41T on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPAR5 | c.671C>A p.T224K | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); called by muse, mutect2
- NDRG3 | c.883C>T p.Q295* (on ENST00000349004 / NM_032013.4; = p.Q283* on NM_022477.4) | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- PRKAA2 | c.24C>A p.D8E | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- RBM15B | c.1179_1197del p.K394Efs*2 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel
- SCN7A | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SMARCAL1 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, varscan2
- TMEM229A | c.90G>C p.E30D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2
- CFAP47 | c.4515A>C p.S1505= | Silent (SNP) | VAF 169/346 reads (49%) | called by muse, mutect2, varscan2
- LRRK1 | c.1584T>A p.G528= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- NKAPL | c.933T>C p.Y311= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs781194861, COSV59196981; called by muse, mutect2
- VWC2 | c.555G>C p.P185= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, varscan2
- ZMYND8 | c.2112C>T p.G704= (on ENST00000311275 / NM_001363741.2; = p.G724= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/175 reads (17%) | called by muse, mutect2, varscan2
